Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A113, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A113-01A (Primary Tumor).

[page 1 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22-0

1/24/11 ju

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

1006 A1 A2 B1 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12 C13 C14
C15 C16

Liver (460 grams, 17.5 x 7.9 x 3.8 cm) gallbladder (7.2 x 3.5 x 3.1 cm), omentum biopsy (2 pieces 2.6 x 0.8 x 0.5 cm) and hepatic artery lymph node.

DIAGNOSIS:

Liver and gallbladder, resection: Grade 3 of 4, hepatocellular carcinoma, usual type, forming a hilar mass 4.8 x 4.3 x 3.2 cm involving segments V and VIII abutting the gallbladder, but not involving it. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 0.7 cm microscopically. Angiolymphatic invasion is identified (by VVG stain) within the tumor however, extratumoral vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing type. The adjacent liver parenchyma is non-cirrhotic. The gallbladder shows subacute and chronic cholecystitis with cholelithiasis (3 mixed stones). All surgical margins are free of tumor, closest 0.7 cm.

Immunoperoxidase studies were performed on paraffin sections of the liver mass using antibodies directed against the following antigens: Hep-1, pCEA, keratin, TTF-1, CD10, mucicarmine, albumin ISH, and VVG. The tumor cells are positive for albumin RNA by ISH with patchy strong staining for keratin, Hep-1 with focal focal canalicular pCEA positivity, and patchy cytoplasmic TTF-1 positivity. The tumor cells are negative for CD10 and mucicarmine. These findings support the H&E diagnosis.

Omentum, biopsy: Fat necrosis negative for malignancy.

Lymph node, hepatic artery, excision: A single hepatic artery lymph node is negative for tumor.

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver and gallbladder, resection: Hepatocellular carcinoma. HOLD to grade.

TIIPAA Discrepancy		

[page 2 of 4]
1CD-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: liver C22-0

1/24/11 *ju*

Patient Key:

Surgical date:

TISSUE DESCRIPTION:

A1 A2 B1 C1 C2 C3 C4 C5 C6 C7 C8 C9 C10 C11 C12 C13 C14
C15 C16

Liver (460 grams, 17.5 x 7.9 x 3.8 cm) gallbladder (7.2 x 3.5 x 3.1 cm), omentum biopsy (2 pieces 2.6 x 0.8 x 0.5 cm) and hepatic artery lymph node.

DIAGNOSIS:

Liver and gallbladder, resection: Grade 3 of 4, hepatocellular carcinoma, usual type, forming a hilar mass 4.8 x 4.3 x 3.2 cm involving segments V and VIII abutting the gallbladder, but not involving it. The hepatic capsule is free of tumor. The surgical margins are free of tumor, the clearance being 0.7 cm microscopically. Angiolymphatic invasion is identified (by VVG stain) within the tumor however, extratumoral vascular invasion is not identified. The tumor is partially encapsulated, infiltration of parenchyma being of the pushing type. The adjacent liver parenchyma is non-cirrhotic. The gallbladder shows subacute and chronic cholecystitis with cholelithiasis (3 mixed stones). All surgical margins are free of tumor, closest 0.7 cm.

Immunoperoxidase studies were performed on paraffin sections of the liver mass using antibodies directed against the following antigens: Hep-1, pCEA, keratin, TTF-1, CD10, mucicarmine, albumin ISH, and VVG. The tumor cells are positive for albumin RNA by ISH with patchy strong staining for keratin, Hep-1 with focal focal canalicular pCEA positivity, and patchy cytoplasmic TTF-1 positivity. The tumor cells are negative for CD10 and mucicarmine. These findings support the H&E diagnosis.

Omentum, biopsy: Fat necrosis negative for malignancy.

Lymph node, hepatic artery, excision: A single hepatic artery lymph node is negative for tumor.

PRELIMINARY FROZEN SECTION CONSULTATION:

Liver and gallbladder, resection: Hepatocellular carcinoma. HOLD to grade.

[page 3 of 4]
Liver • Digestive System CAP Approved

* Data elements *with asterisks* are *not required* for accreditation purposes for the Commission on Cancer. These elements may be clinically important, but are not yet validated or regularly used in patient management. Alternatively, the necessary data may not be available to the pathologist at the time of pathologic assessment of this specimen.

LIVER: Resection

Patient name: (to be de-identified) Patient Key:

Surgical pathology number:

Surgery Date:

MACROSCOPIC

Specimen Type

- ☐ Right lobectomy
- ☒ Extended right lobectomy
- ☒ Medial segmentectomy
- ☐ Left lateral segmentectomy
- ☐ Total left lobectomy
- ☐ Explanted liver
- ☒ Other (specify): Resection (Seg. V, VII)
- ☐ Not specified

Focality

- ☒ Solitary (specify location): Segment V, VII
- ☐ Multiple (specify location): _____

Tumor Size

Greatest dimension: 4.8 cm

*Additional dimensions: 4.3 x 2.2 cm

☐ Cannot be determined (see Comment)

MICROSCOPIC

Histologic Type

- ☒ Hepatocellular carcinoma
- ☐ Fibrolamellar hepatocellular carcinoma variant (specify): _____
- ☐ Combined hepatocellular and cholangiocarcinoma
- ☐ Cholangiocarcinoma, intrahepatic
- ☐ Bile duct cystadenocarcinoma
- ☐ Undifferentiated carcinoma
- ☐ Other (specify): _____
- ☐ Carcinoma, type cannot be determined

Histologic Grade

- ☐ Not applicable
- ☐ GX: Cannot be assessed
- ☐ GI: Well differentiated
- ☐ GII: Moderately differentiated
- ☒ GIII: Poorly differentiated
- ☐ GIV: Undifferentiated/anaplastic
- ☐ Other (specify): _____

[page 4 of 4]
Pathologic Staging (pTNM)

Primary Tumor (pT)

- ☐ pTX: Cannot be assessed
- ☐ pT0: No evidence of primary tumor
- ☒ pT1: Solitary tumor with no vascular invasion
- ☒ pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm
- ☐ pT3: Multiple tumors more than 5 cm or tumor involving a major branch of the portal or hepatic vein(s)
- ☐ pT4: Tumor(s) with direct invasion of adjacent organs other than the gallbladder or perforation of visceral peritoneum

Regional Lymph Nodes (pN)

- ☒ pNX: Cannot be assessed
- ☒ pN0: No regional lymph node metastasis
- ☐ pN1: Regional lymph node metastasis

Specify: Number examined: 1

Number involved: 0

Distant Metastasis (pM)

- ☒ pMX: Cannot be assessed
- ☐ pM1: Distant metastasis

*Specify site(s), if known: _____

Margins (check all that apply)

Parenchymal Margin

- ☒ Cannot be assessed
- ☒ Uninvolved by invasive carcinoma
- Distance of invasive carcinoma from closest margin: 20 mm
- Specify margin: _____

- ☐ Involved by invasive carcinoma

Bile Duct Margin (Cholangiocarcinoma Only)

- ☐ Cannot be assessed
- ☐ Uninvolved by invasive carcinoma
- * ☐ Carcinoma in situ absent
- * ☐ Carcinoma in situ present
- ☐ Involved by invasive carcinoma

Other Margin

Specify margin: _____

- ☐ Cannot be assessed
- ☐ Uninvolved by invasive carcinoma
- ☐ Involved by invasive carcinoma

***Venous (Large Vessel) Invasion (V)**

- * ☒ Absent
- * ☐ Present
- * ☐ Indeterminate

***Additional Pathologic Findings (check all that apply)**

- * ☒ None identified
- * ☐ Hepatocellular dysplasia
- * ☐ Ductal dysplasia
- * ☐ Cirrhosis/fibrosis
- * ☐ Iron overload
- * ☐ Hepatitis (specify type): _____
- * ☐ Other (specify): _____

Source: NCI Genomic Data Commons file c4ed9c5d-1dcc-4228-a226-998d4aef9c7f (TCGA-DD-A113.F0D7BCB4-D3C3-491A-BDE2-8E77E77F1655.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).